Somatic mutation profile of tumor specimen 0DTUIJ from CCDI case PBCJWK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 2.0 years (722 days).
Specimen 0DTUIJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3495b53-3d90-449f-b885-6ee0685eb711.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTUI1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/017c7689-047d-4837-8405-c520011a1fe5

The open-access MAF lists 22 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, 3'UTR 3, Frame Shift Ins 1, 5'UTR 1, 3'Flank 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.337_339del p.L113del | In Frame Del (DEL) | VAF 271/970 reads (28%) | hotspot (GDC flag); called by mutect2, varscan2
- ADGB | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 311/1769 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs759180685, COSV58856490; called by muse, mutect2, varscan2
- CCDC168 | c.6443G>T p.G2148V | Missense Mutation (SNP) | VAF 190/1061 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs1271351274; called by muse, mutect2, varscan2
- PAXBP1 | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 299/1498 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.47); catalogued as rs770634324; called by muse, mutect2, varscan2
- SEC16B | c.1299dup p.S434Qfs*14 | Frame Shift Ins (INS) | VAF 120/771 reads (16%) | catalogued as rs768388757; called by mutect2, varscan2
- UGT1A4 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 44/972 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1422028440; called by muse, mutect2
- HELLS | c.1630G>C p.A544P | Missense Mutation (SNP) | VAF 120/718 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA11 | c.1294G>T p.V432F | Missense Mutation (SNP) | VAF 87/614 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- OCLN | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 169/1065 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHAC1 | c.2098C>T p.L700F | Missense Mutation (SNP) | VAF 106/794 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRG2 | c.212A>T p.D71V | Missense Mutation (SNP) | VAF 57/365 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- SLC6A19 | c.1355A>G p.K452R | Missense Mutation (SNP) | VAF 96/801 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PAPOLB | c.1746C>A p.T582= | Silent (SNP) | VAF 45/946 reads (5%) | called by muse, mutect2
- PCDHA13 | c.1591T>C p.L531= | Silent (SNP) | VAF 17/396 reads (4%) | catalogued as rs1554180306, COSV56546758; called by muse, mutect2
- RUNX3 | c.420C>T p.F140= | Silent (SNP) | VAF 141/912 reads (15%) | catalogued as COSV100137078; called by muse, mutect2, varscan2
- TRIM35 | c.1161C>T p.S387= | Silent (SNP) | VAF 123/944 reads (13%) | catalogued as rs1191669035; called by muse, mutect2, varscan2
- ASXL3 | c.*2110C>T | 3'UTR (SNP) | VAF 22/82 reads (27%) | catalogued as rs141257617; called by muse, mutect2, varscan2
- CASP8 | chr2:201286626 ins T | 3'Flank (INS) | VAF 228/936 reads (24%) | catalogued as rs748265805; called by mutect2, varscan2
- CHCHD5 | c.-90C>A | 5'UTR (SNP) | VAF 70/264 reads (27%) | catalogued as rs943524959, COSV100260733; called by muse, mutect2, varscan2
- HMGB1 | c.*85T>C | 3'UTR (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100360835; called by muse, mutect2
- PINX1 | c.*88A>G | 3'UTR (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2
- PPIP5K2 | c.3097-63G>T | Intron (SNP) | VAF 64/268 reads (24%) | called by muse, mutect2, varscan2
